Gene-level copy-number profile of tumor specimen TCGA-23-2084-01A from TCGA case TCGA-23-2084, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 45.2 years (16,493 days).
Specimen TCGA-23-2084-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d92637ed-8213-4983-b661-16563f7ac3d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-2084-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c63c8f33-60a3-4ba9-b144-b5983c48595d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 377; copy number 2: 18,201; copy number 3: 16,726; copy number 4: 18,813; copy number 5: 4,013; copy number 6: 1,008; copy number 8: 142; copy number 9: 321; copy number 11: 209.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-2084-01A-02D-0663-01): tumor purity 0.69, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:20,246,165–20,372,769, 4 genes: LZTS1, LZTS1-AS1, RNA5SP257, AC023403.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 530 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:101,177,878–142,812,120, 530 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 336. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
